Somatic mutation profile of tumor specimen TCGA-D8-A1JN-01A (aliquot TCGA-D8-A1JN-01A-11D-A13L-09) from TCGA case TCGA-D8-A1JN, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Lobular carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIIC; Age at diagnosis: 80.3 years (29,331 days).
Specimen TCGA-D8-A1JN-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3f58ddf4-f74b-47fe-92d6-0c9e86472186.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-D8-A1JN-10A (Blood Derived Normal), aliquot TCGA-D8-A1JN-10A-01D-A13O-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bd8ae7a5-5e72-4664-aa5c-28b730bc0fd8

The open-access MAF lists 176 somatic variants for this specimen: 116 protein-altering or splice-affecting, 54 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 98, Silent 54, Nonsense Mutation 10, Frame Shift Del 3, Intron 3, 5'UTR 2, Frame Shift Ins 2, Splice Site 2, Splice Region 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NF1 | c.1039C>T p.Q347* | Nonsense Mutation (SNP) | VAF 49/58 reads (84%) | catalogued as rs1555610910, CS086356, COSV62204363; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 32/63 reads (51%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs104886003, CM126692, COSV55873239, COSV55878227; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ABRAXAS2 | c.1132G>A p.E378K | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.048); catalogued as COSV53716958; called by muse, mutect2, varscan2
- ACBD3 | c.1568G>C p.R523T | Missense Mutation (SNP) | VAF 27/96 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV64730385; called by muse, mutect2, varscan2
- ACTN4 | c.979G>A p.E327K | Missense Mutation (SNP) | VAF 31/72 reads (43%) | SIFT tolerated (0.64); PolyPhen benign (0.027); catalogued as COSV53142611; called by muse, mutect2, varscan2
- ADAM29 | c.2409G>C p.Q803H | Missense Mutation (SNP) | VAF 62/143 reads (43%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.265); catalogued as rs749271503, COSV63663923; called by muse, mutect2, varscan2
- ADCY9 | c.4027G>A p.E1343K | Missense Mutation (SNP) | VAF 79/194 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.408); catalogued as rs1368722853, COSV53574571; called by muse, mutect2, varscan2
- AMER1 | c.721C>G p.P241A | Missense Mutation (SNP) | VAF 26/52 reads (50%) | SIFT tolerated (0.54); PolyPhen benign (0.253); catalogued as COSV57661254; called by muse, mutect2, varscan2
- ANKRD11 | c.7493C>T p.A2498V | Missense Mutation (SNP) | VAF 18/22 reads (82%) | SIFT deleterious (0.01); PolyPhen benign (0.338); catalogued as rs1052222126, COSV56361812; called by muse, mutect2, varscan2
- ARHGAP35 | c.3090G>C p.E1030D | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT tolerated (0.29); PolyPhen benign (0.283); catalogued as COSV68331638; called by muse, mutect2, varscan2
- ARSK | c.1159G>C p.E387Q | Missense Mutation (SNP) | VAF 53/158 reads (34%) | SIFT tolerated (0.27); PolyPhen benign (0.021); catalogued as COSV66169716; called by muse, mutect2, varscan2
- ATG4B | c.1112C>T p.S371F | Missense Mutation (SNP) | VAF 46/107 reads (43%) | SIFT tolerated (0.25); PolyPhen benign (0.001); catalogued as COSV99994938; called by muse, mutect2, varscan2
- B3GNT8 | c.715G>A p.V239M | Missense Mutation (SNP) | VAF 18/22 reads (82%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs747886687, COSV54197290; called by muse, varscan2
- BANK1 | c.1018T>G p.F340V | Missense Mutation (SNP) | VAF 43/91 reads (47%) | SIFT tolerated (0.2); PolyPhen benign (0.005); catalogued as COSV59843260; called by muse, mutect2, varscan2
- BCHE | c.644G>A p.G215E | Missense Mutation (SNP) | VAF 6/75 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100013028; called by muse, mutect2
- C1orf162 | c.256C>G p.L86V | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.811); catalogued as COSV100636250; called by muse, mutect2
- CCDC22 | c.1713C>G p.I571M | Missense Mutation (SNP) | VAF 16/33 reads (48%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.879); catalogued as COSV66051442; called by muse, mutect2, varscan2
- CDK8 | c.790G>A p.D264N | Missense Mutation (SNP) | VAF 45/88 reads (51%) | SIFT tolerated (0.13); PolyPhen benign (0.073); catalogued as COSV67420900; called by muse, mutect2, varscan2
- CDKL1 | c.124G>A p.D42N | Missense Mutation (SNP) | VAF 44/102 reads (43%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as COSV53579701; called by muse, mutect2, varscan2
- CEP120 | c.2158G>T p.E720* | Nonsense Mutation (SNP) | VAF 56/129 reads (43%) | catalogued as COSV60265705; called by muse, mutect2, varscan2
- CHD4 | c.2926A>T p.I976F (on ENST00000357008 / NM_001363606.2; = p.I989F on NM_001273.5) | Missense Mutation (SNP) | VAF 41/112 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV58901736; called by muse, mutect2, varscan2
- CHD4 | c.100+1G>A p.X34_splice | Splice Site (SNP) | VAF 10/25 reads (40%) | catalogued as COSV58901747; called by muse, mutect2, varscan2
- CHM | c.158C>T p.S53L | Missense Mutation (SNP) | VAF 36/71 reads (51%) | SIFT deleterious (0.01); PolyPhen benign (0.408); catalogued as COSV62565177; called by muse, mutect2, varscan2
- CPSF6 | c.1624C>T p.R542C | Missense Mutation (SNP) | VAF 46/102 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV57014830; called by muse, mutect2, varscan2
- CSMD2 | c.8963G>T p.R2988I | Missense Mutation (SNP) | VAF 50/111 reads (45%) | SIFT tolerated (0.28); PolyPhen benign (0.326); catalogued as COSV53915830, COSV53941693; called by muse, mutect2, varscan2
- DBR1 | c.568C>G p.L190V | Missense Mutation (SNP) | VAF 25/58 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as COSV53429705, COSV53429918; called by muse, mutect2, varscan2
- DDX54 | c.2372G>A p.R791Q | Missense Mutation (SNP) | VAF 77/165 reads (47%) | SIFT tolerated (0.46); PolyPhen benign (0.001); catalogued as rs1404317942, COSV58373741; called by muse, mutect2, varscan2
- DNAJB5 | c.694G>A p.D232N | Missense Mutation (SNP) | VAF 18/38 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.875); catalogued as rs1312203416, COSV56625712; called by muse, mutect2, varscan2
- DOCK9 | c.5422G>C p.D1808H (on ENST00000376460 / NM_001366676.2; = p.D1809H on NM_015296.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 100/225 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV59630555; called by muse, mutect2, varscan2
- DSP | c.2956C>T p.Q986* | Nonsense Mutation (SNP) | VAF 26/67 reads (39%) | catalogued as CM1310184, COSV101131397, COSV65793042; called by muse, mutect2, varscan2
- DUOX2 | c.1951G>A p.E651K | Missense Mutation (SNP) | VAF 29/60 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.463); catalogued as COSV66532358; called by muse, mutect2, varscan2
- DZANK1 | c.600G>A p.M200I (on ENST00000262547 / NM_001099407.1; = p.M1? on NM_018152.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 51/137 reads (37%) | SIFT tolerated (0.08); PolyPhen benign (0.173); catalogued as COSV52751574; called by muse, mutect2, varscan2
- EGR2 | c.1273G>A p.E425K | Missense Mutation (SNP) | VAF 59/159 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.677); catalogued as COSV54347060; called by muse, mutect2, varscan2
- ESPL1 | c.3914C>G p.S1305* | Nonsense Mutation (SNP) | VAF 20/36 reads (56%) | catalogued as COSV57759752; called by muse, mutect2, varscan2
- FAM162A | c.102G>C p.L34F | Missense Mutation (SNP) | VAF 49/123 reads (40%) | SIFT tolerated (0.07); PolyPhen benign (0.037); catalogued as COSV51657682; called by muse, mutect2, varscan2
- FN1 | c.1717G>A p.G573R | Missense Mutation (SNP) | VAF 52/119 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60553844; called by muse, mutect2, varscan2
- FOXA1 | c.642G>T p.W214C | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51646120, COSV99164034; called by muse, mutect2, varscan2
- FREM2 | c.7877T>A p.F2626Y | Missense Mutation (SNP) | VAF 8/84 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.786); catalogued as COSV54839025; called by muse, mutect2, varscan2
- FSCB | c.1066G>A p.E356K | Missense Mutation (SNP) | VAF 26/78 reads (33%) | SIFT tolerated (0.11); PolyPhen benign (0.303); catalogued as COSV61218186; called by muse, mutect2, varscan2
- GANAB | c.1083C>G p.I361M | Missense Mutation (SNP) | VAF 36/102 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.165); catalogued as COSV60465004; called by muse, mutect2, varscan2
- GORAB | c.74C>T p.P25L | Missense Mutation (SNP) | VAF 17/64 reads (27%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.943); catalogued as COSV63026201; called by muse, mutect2, varscan2
- GPR153 | c.809G>A p.R270Q | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.571); catalogued as rs774162111, COSV64938378; called by muse, mutect2
- GRM3 | c.1427G>T p.G476V | Missense Mutation (SNP) | VAF 31/51 reads (61%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.799); catalogued as COSV64472312; called by muse, mutect2, varscan2
- HERC1 | c.3911G>A p.R1304Q | Missense Mutation (SNP) | VAF 59/142 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs1191941942, COSV71246018; called by muse, mutect2, varscan2
- INCENP | c.901C>G p.Q301E | Missense Mutation (SNP) | VAF 10/19 reads (53%) | SIFT deleterious (0.02); PolyPhen benign (0.011); catalogued as COSV53916248; called by muse, mutect2, varscan2
- IRF3 | c.1004G>A p.G335E | Missense Mutation (SNP) | VAF 11/20 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1226124645, COSV55866489; called by muse, mutect2, varscan2
- IRS1 | c.2199G>A p.M733I | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT tolerated (0.85); PolyPhen benign (0); catalogued as COSV59336635; called by muse, mutect2, varscan2
- KASH5 | c.1057G>A p.E353K | Missense Mutation (SNP) | VAF 41/96 reads (43%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.888); catalogued as rs1215770515, COSV71358029; called by muse, mutect2, varscan2
- KCTD10 | c.727G>A p.E243K | Missense Mutation (SNP) | VAF 9/13 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV57326601, COSV99949181; called by muse, mutect2, varscan2
- KRT73 | c.74C>T p.S25L | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as rs745497162, COSV59839409; called by muse, varscan2
- KRT73 | c.26C>T p.S9L | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT tolerated (0.06); PolyPhen benign (0.028); catalogued as rs114162070, COSV59839418; called by muse, varscan2
- KRTAP10-1 | c.492C>G p.C164W | Missense Mutation (SNP) | VAF 72/183 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.359); catalogued as COSV59963914; called by muse, mutect2, varscan2
- LIFR | c.2128C>T p.Q710* | Nonsense Mutation (SNP) | VAF 43/116 reads (37%) | catalogued as COSV54690860; called by muse, mutect2, varscan2
- LRSAM1 | c.1267G>A p.E423K | Missense Mutation (SNP) | VAF 48/92 reads (52%) | SIFT tolerated (0.12); PolyPhen benign (0.048); catalogued as rs767351229, COSV55938308; called by muse, mutect2, varscan2
- LZTR1 | c.856G>A p.G286R | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs773016962, CM151192, COSV53147760; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MCL1 | c.724G>A p.D242N | Missense Mutation (SNP) | VAF 32/102 reads (31%) | SIFT tolerated (0.11); PolyPhen benign (0.268); catalogued as COSV100329510, COSV57190396; called by muse, mutect2, varscan2
- MDGA2 | c.2194G>T p.D732Y (on ENST00000399232 / NM_001113498.2; = p.D434Y on NM_182830.4) | Missense Mutation (SNP) | VAF 68/158 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.712); catalogued as COSV100637282, COSV62094267; called by muse, mutect2, varscan2
- MED6 | c.517C>T p.Q173* | Nonsense Mutation (SNP) | VAF 42/99 reads (42%) | catalogued as COSV56450223; called by muse, mutect2, varscan2
- MEPCE | c.1933G>C p.E645Q | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.659); catalogued as COSV52769258; called by muse, mutect2, varscan2
- MPEG1 | c.79G>T p.D27Y | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT tolerated (0.06); PolyPhen benign (0.037); catalogued as COSV57091042; called by muse, mutect2, varscan2
- MUC16 | c.4834G>A p.D1612N | Missense Mutation (SNP) | VAF 79/179 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.01); catalogued as COSV67468832; called by muse, mutect2, varscan2
- MX2 | c.649G>A p.E217K | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT tolerated (0.07); PolyPhen benign (0.06); catalogued as COSV58096663; called by muse, mutect2, varscan2
- NOC3L | c.1258-1G>T p.X420_splice | Splice Site (SNP) | VAF 59/159 reads (37%) | catalogued as COSV64929946; called by muse, mutect2, varscan2
- NOL8 | c.69C>A p.D23E | Missense Mutation (SNP) | VAF 36/118 reads (31%) | SIFT tolerated (0.43); PolyPhen possibly damaging (0.625); catalogued as rs1329576993, COSV62635524; called by muse, mutect2, varscan2
- NONO | c.911G>A p.R304H | Missense Mutation (SNP) | VAF 21/50 reads (42%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as COSV52137816; called by muse, mutect2, varscan2
- NOS3 | c.2224G>A p.E742K | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as rs765169676, COSV52486396, COSV52492850, COSV52495663; called by muse, mutect2
- NUS1 | c.353C>G p.A118G | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV63844206; called by muse, mutect2, varscan2
- OBP2A | c.352C>T p.R118C | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.72); catalogued as rs375157638, COSV59790844; called by muse, mutect2, varscan2
- OR10Z1 | c.751C>T p.H251Y | Missense Mutation (SNP) | VAF 52/153 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.012); catalogued as COSV63523956; called by muse, mutect2, varscan2
- OR5B12 | c.49G>A p.D17N | Missense Mutation (SNP) | VAF 19/42 reads (45%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0.005); catalogued as COSV56905178; called by muse, mutect2, varscan2
- PARP4 | c.1843G>A p.D615N | Missense Mutation (SNP) | VAF 27/80 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV67961999; called by muse, mutect2, varscan2
- PARP6 | c.715C>T p.Q239* | Nonsense Mutation (SNP) | VAF 12/23 reads (52%) | catalogued as COSV53002042; called by muse, mutect2, varscan2
- PCDHGA2 | c.1047G>A p.M349I | Missense Mutation (SNP) | VAF 24/48 reads (50%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV53955545; called by muse, mutect2, varscan2
- PCSK1 | c.1098G>A p.T366= | Splice Region (SNP) | VAF 29/74 reads (39%) | catalogued as rs1478328299, COSV60735501; called by muse, mutect2, varscan2
- PCYOX1 | c.143C>T p.S48L | Missense Mutation (SNP) | VAF 58/131 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as rs756161282, COSV52476531; called by muse, mutect2, varscan2
- PEX1 | c.3358G>T p.E1120* | Nonsense Mutation (SNP) | VAF 49/112 reads (44%) | catalogued as COSV50399239; called by muse, mutect2, varscan2
- POLR2J | c.83C>A p.P28H | Missense Mutation (SNP) | VAF 151/452 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.846); catalogued as COSV53000182; called by muse, mutect2, varscan2
- PPFIA3 | c.1382C>T p.S461F | Missense Mutation (SNP) | VAF 23/58 reads (40%) | SIFT tolerated (0.23); PolyPhen benign (0.308); catalogued as COSV61951951; called by muse, mutect2, varscan2
- PRAMEF5 | c.1322G>C p.R441T | Missense Mutation (SNP) | VAF 8/92 reads (9%) | SIFT tolerated (0.3); PolyPhen benign (0.015); catalogued as COSV100871352; called by muse, mutect2, varscan2
- PRDM14 | c.593C>T p.T198M | Missense Mutation (SNP) | VAF 32/69 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV52572639; called by muse, mutect2, varscan2
- PRKCB | c.1093G>A p.D365N | Missense Mutation (SNP) | VAF 54/108 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.19); catalogued as COSV57780889; called by muse, mutect2, varscan2
- PRRC2C | c.5803C>G p.Q1935E (on ENST00000367742; = p.Q1933E on NM_015172.4) | Missense Mutation (SNP) | VAF 47/151 reads (31%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.054); catalogued as COSV58905993; called by muse, mutect2, varscan2
- PTK7 | c.2293G>A p.E765K | Missense Mutation (SNP) | VAF 28/59 reads (47%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.954); catalogued as COSV57848823; called by muse, mutect2, varscan2
- PTPRB | c.499G>A p.E167K | Missense Mutation (SNP) | VAF 40/114 reads (35%) | SIFT tolerated (0.13); PolyPhen benign (0.011); catalogued as COSV54241749; called by muse, mutect2, varscan2
- RAB35 | c.135C>G p.F45L | Missense Mutation (SNP) | VAF 36/74 reads (49%) | SIFT deleterious (0); PolyPhen benign (0.423); catalogued as COSV57567322, COSV57567659; called by muse, mutect2, varscan2
- RNF182 | c.352C>G p.L118V | Missense Mutation (SNP) | VAF 25/57 reads (44%) | SIFT tolerated (0.53); PolyPhen benign (0.063); catalogued as COSV70369293, COSV99066948; called by muse, mutect2, varscan2
- SEMA5B | c.314C>A p.T105N | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.037); catalogued as COSV52098890; called by muse, mutect2, varscan2
- SHMT2 | c.711G>A p.M237I | Missense Mutation (SNP) | VAF 17/35 reads (49%) | SIFT tolerated (0.24); PolyPhen benign (0.005); catalogued as COSV61074074; called by muse, mutect2, varscan2
- SLC22A25 | c.242C>G p.S81* | Nonsense Mutation (SNP) | VAF 69/146 reads (47%) | catalogued as COSV60595639; called by muse, mutect2, varscan2
- SLC26A3 | c.2269G>T p.E757* | Nonsense Mutation (SNP) | VAF 48/127 reads (38%) | catalogued as COSV100385298, COSV60640493; called by muse, mutect2, varscan2
- SPTA1 | c.3946G>A p.E1316K | Missense Mutation (SNP) | VAF 44/141 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV63753831; called by muse, mutect2, varscan2
- STX3 | c.460G>A p.E154K | Missense Mutation (SNP) | VAF 29/58 reads (50%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs201661485, COSV55695114; called by muse, mutect2, varscan2
- SV2A | c.274G>A p.E92K | Missense Mutation (SNP) | VAF 26/90 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as COSV64964904; called by muse, mutect2, varscan2
- SZT2 | c.3431C>T p.S1144L (on ENST00000634258 / NM_001365999.1; = p.S1087L on NM_015284.4) | Missense Mutation (SNP) | VAF 37/98 reads (38%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as COSV65170170; called by muse, mutect2, varscan2
- TENM1 | c.7918G>A p.E2640K | Missense Mutation (SNP) | VAF 57/126 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.664); catalogued as rs772723685, COSV64432648; called by muse, mutect2, varscan2
- THSD7B | c.2197C>T p.P733S | Missense Mutation (SNP) | VAF 90/199 reads (45%) | SIFT deleterious (0.03); PolyPhen benign (0.31); catalogued as COSV55690391; called by muse, mutect2, varscan2
- TMC5 | c.1613C>G p.T538S (on ENST00000396229 / NM_001105248.1; = p.T292S on NM_024780.5) | Missense Mutation (SNP) | VAF 70/177 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.035); catalogued as COSV54904506; called by muse, mutect2, varscan2
- TMCC3 | c.1092G>C p.K364N | Missense Mutation (SNP) | VAF 32/66 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV54154628; called by muse, mutect2, varscan2
- TTI1 | c.2902G>A p.A968T | Missense Mutation (SNP) | VAF 17/37 reads (46%) | SIFT tolerated (0.06); PolyPhen benign (0.056); catalogued as rs139243887; called by muse, mutect2, varscan2
- TTN | c.37345G>C p.D12449H (on ENST00000591111; = p.D5025H on NM_003319.4) | Missense Mutation (SNP) | VAF 27/56 reads (48%) | PolyPhen possibly damaging (0.772); catalogued as COSV60087647, COSV60285664; called by muse, mutect2, varscan2
- TTN | c.2562G>C p.K854N (on ENST00000591111; = p.K808N on NM_003319.4) | Missense Mutation (SNP) | VAF 24/48 reads (50%) | PolyPhen probably damaging (0.964); catalogued as COSV60087698; called by muse, mutect2, varscan2
- UBIAD1 | c.676G>A p.E226K | Missense Mutation (SNP) | VAF 41/86 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.728); catalogued as rs755253867, COSV65147776; called by muse, mutect2, varscan2
- USP7 | c.3011G>A p.G1004E | Missense Mutation (SNP) | VAF 34/80 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61214852; called by muse, mutect2, varscan2
- ZC3H6 | c.2511C>G p.F837L | Missense Mutation (SNP) | VAF 17/21 reads (81%) | SIFT tolerated (0.1); PolyPhen benign (0.034); catalogued as COSV59667959, COSV59670771; called by muse, mutect2, varscan2
- ZNF106 | c.1122G>C p.M374I | Missense Mutation (SNP) | VAF 58/152 reads (38%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as COSV55517058; called by muse, mutect2, varscan2
- ZNF114 | c.430G>C p.D144H | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.718); catalogued as COSV59944424; called by muse, mutect2, varscan2
- ZNF121 | c.232C>T p.H78Y | Missense Mutation (SNP) | VAF 52/124 reads (42%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs751459507, COSV57551672; called by muse, mutect2, varscan2
- ZNF41 | c.2150G>C p.R717T | Missense Mutation (SNP) | VAF 54/140 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as COSV57442767; called by muse, mutect2, varscan2
- ZNF629 | c.377C>T p.P126L | Missense Mutation (SNP) | VAF 9/14 reads (64%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.013); catalogued as COSV52698686; called by muse, mutect2, varscan2
- ZNF681 | c.305G>A p.R102K | Missense Mutation (SNP) | VAF 47/113 reads (42%) | SIFT tolerated (0.18); PolyPhen benign (0.056); catalogued as rs780800373, COSV68073967, COSV68074385; called by muse, mutect2, varscan2
- ZNF780B | c.2323C>T p.H775Y | Missense Mutation (SNP) | VAF 54/101 reads (53%) | SIFT deleterious (0.01); PolyPhen benign (0.14); catalogued as rs1362630887, COSV55464540; called by muse, mutect2, varscan2
- ANKRD24 | c.3336_3339del p.Y1112* | Frame Shift Del (DEL) | VAF 13/46 reads (28%) | called by mutect2, varscan2
- E2F1 | c.361dup p.S121Ffs*9 | Frame Shift Ins (INS) | VAF 19/60 reads (32%) | called by pindel, varscan2
- FOXD4L6 | c.1216del p.C406Afs*22 | Frame Shift Del (DEL) | VAF 11/53 reads (21%) | called by mutect2, pindel, varscan2
- GATA3 | c.1064_1068dup p.K357Lfs*2 | Frame Shift Ins (INS) | VAF 22/47 reads (47%) | called by mutect2, pindel, varscan2
- NIPBL | c.5769_5782del p.A1925Nfs*17 | Frame Shift Del (DEL) | VAF 12/49 reads (24%) | called by mutect2, varscan2
- ADCY8 | c.702G>A p.K234= | Silent (SNP) | VAF 16/32 reads (50%) | catalogued as COSV53909482, COSV53915586; called by muse, mutect2, varscan2
- ADGRE3 | c.1338C>G p.L446= | Silent (SNP) | VAF 28/57 reads (49%) | catalogued as COSV53730872, COSV99505933; called by muse, mutect2, varscan2
- AHNAK2 | c.3303G>T p.V1101= | Silent (SNP) | VAF 54/132 reads (41%) | catalogued as COSV100319064; called by muse, mutect2
- AMIGO3 | c.987C>T p.I329= | Silent (SNP) | VAF 11/21 reads (52%) | catalogued as COSV57538722; called by muse, mutect2, varscan2
- APLP2 | c.954C>T p.P318= | Silent (SNP) | VAF 35/74 reads (47%) | catalogued as rs1427612105, COSV53840967; called by muse, mutect2, varscan2
- BRPF3 | c.2790C>G p.L930= | Silent (SNP) | VAF 15/37 reads (41%) | catalogued as COSV60207624; called by muse, mutect2, varscan2
- C2CD6 | c.1116G>A p.T372= | Silent (SNP) | VAF 27/69 reads (39%) | catalogued as rs895636226, COSV53791228; called by muse, mutect2, varscan2
- CACNA1I | c.2370C>T p.L790= | Silent (SNP) | VAF 48/66 reads (73%) | catalogued as rs775598327, COSV60809403; called by muse, mutect2, varscan2
- CDH26 | c.735C>T p.I245= | Silent (SNP) | VAF 50/93 reads (54%) | catalogued as COSV54847393, COSV54848082; called by muse, mutect2, varscan2
- CPAMD8 | c.4224C>T p.F1408= (on ENST00000651564; = p.F1361= on NM_015692.5) | Silent (SNP) | VAF 18/54 reads (33%) | catalogued as COSV71596638; called by muse, mutect2, varscan2
- ERGIC1 | c.117C>T p.L39= | Silent (SNP) | VAF 151/323 reads (47%) | catalogued as rs774256350, COSV67127992, COSV67128247; called by muse, mutect2, varscan2
- EVI5L | c.996G>A p.Q332= | Silent (SNP) | VAF 15/37 reads (41%) | catalogued as COSV54485867; called by muse, mutect2, varscan2
- FASTK | c.1491G>C p.S497= | Silent (SNP) | VAF 14/27 reads (52%) | catalogued as COSV52540079, COSV52540156; called by muse, mutect2, varscan2
- GRIK3 | c.2691C>T p.F897= | Silent (SNP) | VAF 25/63 reads (40%) | catalogued as COSV66137123, COSV66140348; called by muse, mutect2, varscan2
- IFT122 | c.468C>A p.I156= | Silent (SNP) | VAF 45/113 reads (40%) | catalogued as COSV56203443; called by muse, mutect2, varscan2
- IGKV1-12 | c.207G>T p.L69= | Silent (SNP) | VAF 50/243 reads (21%) | catalogued as rs748135175; called by muse, mutect2, varscan2
- INCENP | c.586C>T p.L196= | Silent (SNP) | VAF 12/26 reads (46%) | catalogued as COSV53916228; called by muse, mutect2, varscan2
- ING1 | c.864C>T p.P288= | Silent (SNP) | VAF 16/27 reads (59%) | catalogued as rs764272577, COSV58169328; called by muse, mutect2, varscan2
- IQSEC1 | c.1500C>T p.L500= | Silent (SNP) | VAF 38/87 reads (44%) | catalogued as COSV56224278; called by muse, mutect2, varscan2
- LGALS9 | c.354C>G p.L118= | Silent (SNP) | VAF 8/130 reads (6%) | called by muse, mutect2
- LIMS1 | c.108C>T p.F36= | Silent (SNP) | VAF 63/199 reads (32%) | catalogued as rs144584482; called by muse, mutect2, varscan2
- MAGI3 | c.1320G>A p.L440= | Silent (SNP) | VAF 37/95 reads (39%) | catalogued as rs1196410187, COSV56836251; called by muse, mutect2, varscan2
- MOV10L1 | c.3051C>A p.I1017= | Silent (SNP) | VAF 65/88 reads (74%) | catalogued as COSV53172208; called by muse, mutect2, varscan2
- MRGBP | c.546C>T p.V182= | Silent (SNP) | VAF 24/58 reads (41%) | catalogued as COSV65111461; called by muse, mutect2, varscan2
- MTUS2 | c.285G>A p.L95= | Silent (SNP) | VAF 18/33 reads (55%) | catalogued as rs1490388176, COSV70916983; called by muse, mutect2, varscan2
- MUC2 | c.1962C>T p.I654= | Silent (SNP) | VAF 25/63 reads (40%) | called by muse, mutect2, varscan2
- OR7D4 | c.420C>A p.L140= | Silent (SNP) | VAF 34/96 reads (35%) | catalogued as COSV58071772; called by muse, mutect2, varscan2
- PDCL | c.489G>A p.E163= | Silent (SNP) | VAF 25/74 reads (34%) | catalogued as rs1564267960, COSV52342666; called by muse, mutect2, varscan2
- POLR1A | c.4050G>C p.L1350= | Silent (SNP) | VAF 43/81 reads (53%) | catalogued as COSV55693438; called by muse, mutect2, varscan2
- POTEM | c.282C>G p.L94= | Silent (SNP) | VAF 22/216 reads (10%) | catalogued as rs755970722, COSV101304741, COSV69152851, COSV69153518; called by muse, varscan2
- PPP1R12B | c.1740C>A p.L580= | Silent (SNP) | VAF 54/189 reads (29%) | catalogued as COSV61117541, COSV61123582; called by muse, mutect2, varscan2
- PRKDC | c.11436G>A p.L3812= | Silent (SNP) | VAF 9/28 reads (32%) | catalogued as COSV58053123; called by muse, mutect2, varscan2
- RBFOX1 | c.240G>C p.T80= | Silent (SNP) | VAF 17/38 reads (45%) | catalogued as rs1006821072, COSV60947779, COSV60960031, COSV60988194; called by muse, mutect2, varscan2
- RNF148 | c.732C>T p.L244= | Silent (SNP) | VAF 46/127 reads (36%) | catalogued as rs775751398, COSV100411797, COSV57364815; called by muse, mutect2, varscan2
- RPF1 | c.201C>T p.F67= | Silent (SNP) | VAF 4/12 reads (33%) | catalogued as COSV65724372; called by muse, mutect2, varscan2
- RTL8A | c.48C>G p.L16= | Silent (SNP) | VAF 17/41 reads (41%) | catalogued as COSV66188606; called by muse, mutect2, varscan2
- SLC15A1 | c.1872G>A p.L624= | Silent (SNP) | VAF 44/87 reads (51%) | catalogued as COSV64731643; called by muse, mutect2, varscan2
- SLC24A1 | c.3157C>T p.L1053= | Silent (SNP) | VAF 176/394 reads (45%) | catalogued as COSV56051947; called by muse, mutect2, varscan2
- SLC34A2 | c.762C>T p.F254= | Silent (SNP) | VAF 38/96 reads (40%) | catalogued as COSV65941631; called by muse, mutect2, varscan2
- SLC43A1 | c.657C>T p.I219= | Silent (SNP) | VAF 30/61 reads (49%) | catalogued as rs774092459, COSV53557446; called by muse, mutect2, varscan2
- SMTN | c.558A>G p.T186= | Silent (SNP) | VAF 9/12 reads (75%) | catalogued as COSV60778640; called by muse, mutect2, varscan2
- SNX27 | c.714A>T p.G238= | Silent (SNP) | VAF 36/90 reads (40%) | catalogued as COSV64326465; called by muse, mutect2, varscan2
- SPART | c.1542G>A p.K514= | Silent (SNP) | VAF 48/102 reads (47%) | catalogued as COSV62085518, COSV99050420; called by muse, mutect2, varscan2
- TAF5L | c.303C>T p.V101= | Silent (SNP) | VAF 9/32 reads (28%) | catalogued as COSV51080441; called by muse, mutect2, varscan2
- TAT | c.1206C>T p.V402= | Silent (SNP) | VAF 21/26 reads (81%) | catalogued as COSV63532933; called by muse, mutect2, varscan2
- TBC1D23 | c.39G>C p.S13= | Silent (SNP) | VAF 8/29 reads (28%) | catalogued as COSV61368133; called by muse, mutect2, varscan2
- TESK2 | c.453T>A p.T151= | Silent (SNP) | VAF 71/129 reads (55%) | catalogued as COSV59152412; called by muse, mutect2, varscan2
- TLR5 | c.2136C>G p.L712= | Silent (SNP) | VAF 9/53 reads (17%) | catalogued as COSV60559250; called by muse, mutect2, varscan2
- TMC6 | c.1530C>T p.I510= | Silent (SNP) | VAF 10/13 reads (77%) | catalogued as rs376404481; called by muse, mutect2, varscan2
- TMEM245 | c.1266C>T p.L422= | Silent (SNP) | VAF 30/74 reads (41%) | catalogued as rs369574982, COSV65822855; called by muse, mutect2, varscan2
- TMPRSS5 | c.954C>G p.L318= | Silent (SNP) | VAF 8/25 reads (32%) | catalogued as COSV55423901; called by muse, mutect2, varscan2
- TPP1 | c.933C>T p.L311= | Silent (SNP) | VAF 19/42 reads (45%) | catalogued as COSV54994235; called by muse, varscan2
- UBA1 | c.3057G>T p.V1019= | Silent (SNP) | VAF 27/62 reads (44%) | catalogued as COSV60112928; called by muse, mutect2, varscan2
- ZNF266 | c.1377C>T p.S459= | Silent (SNP) | VAF 25/56 reads (45%) | catalogued as rs769337149, COSV63222245; called by muse, mutect2, varscan2
- CDH5 | c.-1G>A | 5'UTR (SNP) | VAF 10/13 reads (77%) | catalogued as COSV100439469; called by muse, mutect2, varscan2
- CLCN5 | c.17-33807G>A | Intron (SNP) | VAF 66/135 reads (49%) | catalogued as rs377356657, COSV101067211, COSV101067328; called by muse, mutect2, varscan2
- MEF2C | c.402+182G>A | Intron (SNP) | VAF 54/167 reads (32%) | catalogued as COSV60930607; called by muse, mutect2, varscan2
- RGP1 | c.-30G>A | 5'UTR (SNP) | VAF 35/86 reads (41%) | catalogued as COSV65239587; called by muse, mutect2, varscan2
- SSPOP | n.11630G>A | RNA (SNP) | VAF 14/22 reads (64%) | catalogued as COSV65130521; called by muse, mutect2, varscan2
- SYTL2 | c.1460-3304C>T | Intron (SNP) | VAF 40/81 reads (49%) | catalogued as rs776396570, COSV60357591; called by muse, mutect2, varscan2
